Somatic mutation profile of tumor specimen TCGA-B6-A0RH-01A (aliquot TCGA-B6-A0RH-01A-21D-A10Y-09) from TCGA case TCGA-B6-A0RH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.4 years (18,759 days).
Specimen TCGA-B6-A0RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb0f57fd-dbb7-43a9-99d4-021170c73684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RH-10A (Blood Derived Normal), aliquot TCGA-B6-A0RH-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/311948ec-6cb2-42b1-881a-76639c78c6ee

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 95/149 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 65/130 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TPSD1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs3865205, COSV52973780; called by mutect2, varscan2
- BAHCC1 | c.4573G>C p.E1525Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV57024559; called by muse, varscan2
- CLEC4E | c.42_43del p.G15Mfs*38 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs1398634392; called by pindel, varscan2
- CSGALNACT1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199989662, COSV59975343; called by muse, mutect2, varscan2
- CTSV | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52344237; called by muse, mutect2, varscan2
- DEPDC7 | c.163C>T p.R55* (on ENST00000241051 / NM_001077242.2; = p.R46* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 47/146 reads (32%) | catalogued as rs775626512, COSV53806338; called by muse, mutect2, varscan2
- DTNB | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 45/122 reads (37%) | catalogued as rs1459991772, COSV99977902; called by muse, varscan2
- EPHB2 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV65860819; called by muse, mutect2, varscan2
- FAAP24 | c.243+1G>A p.X81_splice | Splice Site (SNP) | VAF 23/100 reads (23%) | catalogued as rs764408312, COSV54287551; called by muse, mutect2, varscan2
- KAT6B | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV54744316, COSV99768726; called by muse, mutect2, varscan2
- KRT28 | c.660G>C p.E220D | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60684387; called by muse, mutect2, varscan2
- PDGFRB | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.769); catalogued as COSV55802756; called by muse, mutect2, varscan2
- PSEN2 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV60915314; called by muse, mutect2, varscan2
- PTPN22 | c.642T>G p.C214W | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63084545; called by muse, mutect2, varscan2
- RNF135 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60433167; called by muse, mutect2, varscan2
- SH3PXD2B | c.1680T>G p.I560M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV61125528; called by muse, mutect2, varscan2
- SI | c.4474C>T p.R1492* | Nonsense Mutation (SNP) | VAF 76/227 reads (33%) | catalogued as rs747584061, COSV52267155; called by muse, mutect2, varscan2
- SMARCA2 | c.3680A>G p.N1227S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV61805600; called by muse, mutect2, varscan2
- SPATA31D1 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV61193872, COSV61193944; called by muse, mutect2, varscan2
- SVEP1 | c.7901T>C p.F2634S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52837088; called by muse, mutect2, varscan2
- TARS2 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as rs1159704442, COSV60872278, COSV60872303; called by muse, mutect2, varscan2
- TMC5 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV66865156; called by muse, mutect2, varscan2
- TSPAN1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64339535; called by muse, mutect2, varscan2
- WDR7 | c.1616A>T p.D539V | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54350156; called by muse, mutect2, varscan2
- IP6K2 | c.92dup p.C31Wfs*7 | Frame Shift Ins (INS) | VAF 36/108 reads (33%) | called by mutect2, pindel, varscan2
- MAP2K4 | c.633+2dup p.X211_splice | Splice Site (INS) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R14A | c.262_266del p.E88Kfs*77 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | called by mutect2, pindel, varscan2
- FAM71F2 | c.457C>T p.L153= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV66351967; called by muse, varscan2
- MIA3 | c.873G>A p.E291= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV60511132; called by muse, mutect2, varscan2
- MLLT10 | c.189T>A p.T63= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as COSV56993167; called by muse, mutect2, varscan2
- NLRP4 | c.411C>G p.R137= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV100016939; called by muse, mutect2
- SEC24A | c.3114C>T p.F1038= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as COSV67305078; called by muse, mutect2, varscan2
- SYNE2 | c.17040G>A p.R5680= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs778757649, COSV59944260; called by muse, mutect2, varscan2
- TBK1 | c.951A>G p.Q317= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs1181472026, COSV59154332; called by muse, mutect2, varscan2
- VPREB1 | c.147C>T p.I49= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs200837518, COSV56425512; called by muse, mutect2, varscan2
